Somatic mutation profile of tumor specimen MMRF_1801_1_BM_CD138pos (aliquot MMRF_1801_1_BM_CD138pos_T1_KBS5U_L05382) from MMRF case MMRF_1801, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.0 years (23,020 days).
Specimen MMRF_1801_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 468688f1-e40f-4d48-b578-962ff57188eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1801_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1801_1_PB_Whole_C3_KBS5U_L05395; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a854c7f4-ce69-4a11-9879-7a31b7a0a331

The open-access MAF lists 1,475 somatic variants for this specimen: 506 protein-altering or splice-affecting, 213 silent, 756 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 444, 3'UTR 333, Intron 218, Silent 213, 5'UTR 107, 5'Flank 47, Nonsense Mutation 39, 3'Flank 28, RNA 23, Splice Region 11, Splice Site 7, Frame Shift Del 2.

Variants (750 of 1,475; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TULP1 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1313593155, COSV57692577; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCG5 | c.1356G>C p.E452D | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV53210935, COSV53214726; called by muse, mutect2, varscan2
- ABLIM1 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.943); catalogued as rs760317827; called by muse, mutect2, varscan2
- ADCY6 | c.2917C>T p.Q973* | Nonsense Mutation (SNP) | VAF 75/165 reads (45%) | catalogued as rs747921948, COSV57166522; called by muse, mutect2, varscan2
- ADGRV1 | c.5203G>A p.E1735K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67978882; called by muse, mutect2, varscan2
- ADGRV1 | c.7795C>T p.Q2599* | Nonsense Mutation (SNP) | VAF 51/109 reads (47%) | catalogued as rs761372784; called by muse, mutect2, varscan2
- AFDN | c.4450C>A p.Q1484K | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.966); catalogued as COSV60060344; called by muse, mutect2, varscan2
- AGAP3 | c.215C>T p.S72F (on ENST00000622464; = p.S108F on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.454); catalogued as COSV52545212, COSV52545277; called by muse, mutect2, varscan2
- AHNAK2 | c.12478G>C p.E4160Q | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.794); catalogued as rs1462914801; called by muse, mutect2, varscan2
- AHNAK2 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.625); catalogued as rs755905465; called by muse, mutect2, varscan2
- AL592490.1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1270126658, COSV69426590; called by muse, mutect2
- ALOX12 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs776380897, COSV52350402; called by muse, mutect2, varscan2
- AMBRA1 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV54051060; called by muse, mutect2, varscan2
- AMMECR1 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs774068575, COSV99467281; called by muse, mutect2, varscan2
- ANK3 | c.1690-1G>A p.X564_splice | Splice Site (SNP) | VAF 24/46 reads (52%) | catalogued as COSV55082772; called by mutect2, varscan2
- ANKRD2 | c.933G>A p.L311= | Splice Region (SNP) | VAF 37/92 reads (40%) | catalogued as COSV100080761; called by muse, mutect2, varscan2
- AP4B1 | c.1927C>T p.Q643* | Nonsense Mutation (SNP) | VAF 43/83 reads (52%) | catalogued as rs763147902, COSV56727192; called by muse, mutect2, varscan2
- ARHGEF10 | c.986C>T p.T329M (on ENST00000398564; = p.T304M on NM_014629.4) | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs752299513; called by muse, mutect2, varscan2
- ARID1A | c.6547C>T p.R2183C | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61381957; called by muse, mutect2, varscan2
- ARL10 | c.494G>C p.R165P | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100118948; called by muse, mutect2, varscan2
- ATM | c.8081G>A p.G2694E | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53723985; called by muse, mutect2, varscan2
- ATP2C2 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52301652; called by muse, mutect2
- B2M | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs765817584, COSV62562886; called by muse, mutect2, varscan2
- BAIAP2L2 | c.734C>A p.S245* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as rs1282997561; called by muse, mutect2, varscan2
- BOD1L1 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 60/122 reads (49%) | catalogued as COSV50080738; called by muse, mutect2, varscan2
- BPIFB4 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs987026992, COSV100971418; called by muse, mutect2, varscan2
- CA3 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1317786823; called by muse, mutect2, varscan2
- CACNA1A | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.283); catalogued as rs752824390, COSV64197936; called by muse, mutect2, varscan2
- CARD11 | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV101210433, COSV67800265; called by muse, mutect2, varscan2
- CCDC168 | c.18176G>C p.R6059T | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.643); catalogued as COSV59420079; called by muse, mutect2, varscan2
- CCND3 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65912660; called by muse, mutect2, varscan2
- CDH18 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV56949132; called by muse, mutect2, varscan2
- CDK2 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 87/168 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs113816950, COSV99906631; called by muse, mutect2, varscan2
- CEP97 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs775245993; called by muse, mutect2, varscan2
- CHIA | c.1271C>T p.S424L (on ENST00000343320; = p.S316L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs754393219, COSV58475780; called by muse, mutect2, varscan2
- CHRNB1 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 76/150 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV100043856; called by muse, mutect2, varscan2
- CLIP4 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1208638129, COSV99065486; called by muse, mutect2, varscan2
- CNTN4 | c.1747G>C p.D583H | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100639713; called by muse, mutect2, varscan2
- CNTNAP1 | c.1307-1G>A p.X436_splice | Splice Site (SNP) | VAF 56/113 reads (50%) | catalogued as COSV52849983; called by muse, mutect2, varscan2
- CNTNAP2 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 8/133 reads (6%) | catalogued as COSV62156912; called by muse, mutect2
- CNTNAP2 | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs768389541, COSV62162154; called by muse, mutect2, varscan2
- COL18A1 | c.2680G>A p.D894N (on ENST00000359759 / NM_130444.3; = p.D659N on NM_030582.4) | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs369917403, COSV100700451, COSV62707605; called by muse, mutect2
- COL8A1 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs764448644; called by muse, mutect2, varscan2
- CPSF1 | c.2782G>A p.V928M | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs954801800; called by muse, mutect2, varscan2
- CTNNB1 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62694859; called by muse, mutect2, varscan2
- CYB561 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs1184785967, COSV100669095; called by muse, mutect2, varscan2
- DDX24 | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 28/49 reads (57%) | catalogued as COSV52574433; called by muse, mutect2, varscan2
- DNAH3 | c.3056C>T p.T1019M | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1051092511, COSV54525237; called by muse, mutect2, varscan2
- DNPEP | c.408G>A p.W136* | Nonsense Mutation (SNP) | VAF 44/89 reads (49%) | catalogued as rs1225089812; called by muse, mutect2, varscan2
- DOCK11 | c.1369C>A p.Q457K | Missense Mutation (SNP) | VAF 57/57 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV52237048, COSV99354003; called by muse, mutect2, varscan2
- DPPA4 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs761894945, COSV100169305, COSV59510040; called by muse, mutect2
- DRD4 | c.1035G>A p.M345I | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1212259802; called by mutect2, varscan2
- EGR1 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs199695186; called by muse, mutect2, varscan2
- EHMT1 | c.3484G>C p.D1162H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71778746; called by muse, mutect2, varscan2
- ELFN2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750035846, COSV101297632; called by muse, mutect2, varscan2
- ELSPBP1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs752443440, COSV100353702; called by muse, mutect2
- ERBB4 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV61477791; called by muse, mutect2, varscan2
- ESF1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as rs368296225; called by muse, mutect2, varscan2
- EVX1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs1218556170, COSV99763907; called by muse, mutect2, varscan2
- EZH2 | c.2173G>A p.D725N (on ENST00000460911 / NM_001203247.2; = p.D730N on NM_004456.5) | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57451608; called by muse, mutect2, varscan2
- F13A1 | c.2183G>C p.R728T | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV53556886; called by muse, mutect2
- FAM81B | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as COSV99352861; called by muse, mutect2
- FAT1 | c.10468G>A p.E3490K | Missense Mutation (SNP) | VAF 43/44 reads (98%) | SIFT tolerated (0.77); PolyPhen benign (0.111); catalogued as COSV71675791; called by muse, mutect2, varscan2
- FAT4 | c.4561G>C p.D1521H | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101272303, COSV67883643; called by muse, mutect2, varscan2
- FBXL8 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); catalogued as rs751771806, COSV50456818, COSV50457131; called by muse, mutect2, varscan2
- FBXO22 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.003); catalogued as COSV51192639; called by muse, mutect2, varscan2
- FBXO47 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 105/199 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs771919727; called by muse, mutect2, varscan2
- FGF3 | c.280G>T p.G94W | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61925455, COSV61925479; called by muse, mutect2, varscan2
- FILIP1 | c.3455C>G p.S1152C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99031081; called by muse, mutect2, varscan2
- FLT4 | c.2367C>A p.F789L | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV99988857; called by muse, mutect2, varscan2
- FNBP1L | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53095595; called by muse, mutect2, varscan2
- FRMPD2 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs1167089507; called by muse, mutect2, varscan2
- FYCO1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV56119401; called by muse, mutect2, varscan2
- GGCX | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV52089769; called by muse, mutect2, varscan2
- GNAS | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); catalogued as COSV58333722; called by muse, mutect2
- GOLGB1 | c.1542G>C p.Q514H | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV61470566; called by muse, mutect2, varscan2
- GPATCH1 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99403810; called by muse, mutect2, varscan2
- GPR26 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1389105852, COSV52934644; called by muse, mutect2
- H3C7 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 103/108 reads (95%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); catalogued as COSV55099822, COSV55101039; called by muse, mutect2, varscan2
- H3C8 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 78/79 reads (99%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100010159, COSV59952645; called by muse, mutect2, varscan2
- HECTD2 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV99978738; called by muse, mutect2, varscan2
- HHLA1 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.716); catalogued as rs934136184; called by muse, mutect2, varscan2
- HLA-E | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV64927732; called by muse, mutect2, varscan2
- HSPA8 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.672); catalogued as COSV99914358; called by muse, mutect2, varscan2
- IFNA16 | c.491G>A p.W164* | Nonsense Mutation (SNP) | VAF 87/164 reads (53%) | catalogued as rs1416597545, COSV66509786; called by muse, mutect2, varscan2
- IGLV4-60 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 70/73 reads (96%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.551); catalogued as rs190843139, COSV101135241, COSV66503777; called by muse, varscan2
- IGLV4-60 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 76/80 reads (95%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.455); catalogued as rs376786038; called by muse, varscan2
- IGLV6-57 | c.287C>G p.T96S | Missense Mutation (SNP) | VAF 71/76 reads (93%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as rs781649738; called by muse, mutect2
- IL17C | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756584745, COSV54918553; called by muse, mutect2, varscan2
- INHBB | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV54677421; called by muse, mutect2, varscan2
- IRGQ | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.121); catalogued as rs1435382772; called by muse, mutect2, varscan2
- ITGA2B | c.847+5G>C | Splice Region (SNP) | VAF 48/104 reads (46%) | catalogued as rs962643819; called by muse, mutect2, varscan2
- ITGAX | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV51645946; called by muse, mutect2, varscan2
- ITGBL1 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs980393392, COSV101097671; called by muse, mutect2, varscan2
- KIF3C | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53100260; called by muse, mutect2, varscan2
- KLF14 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.127); catalogued as rs1211644838; called by muse, mutect2, varscan2
- KLF2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0.089); catalogued as COSV50179568; called by muse, mutect2, varscan2
- KMT2C | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV51435592, COSV99030432; called by muse, mutect2
- KRT6A | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV58106035; called by muse, mutect2, varscan2
- LCMT2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs1320742528, COSV59789944, COSV59791207; called by muse, mutect2, varscan2
- LIX1L | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); catalogued as rs782185785; called by muse, mutect2, varscan2
- LNX1 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV99820859; called by muse, mutect2
- LPA | c.4480G>A p.E1494K | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.034); catalogued as COSV60300740; called by muse, mutect2, varscan2
- LRRK2 | c.3742G>C p.E1248Q | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54144963; called by muse, mutect2, varscan2
- LTBP1 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1195262586; called by muse, mutect2, varscan2
- LTBP4 | c.1751G>A p.R584Q (on ENST00000308370 / NM_001042544.1; = p.R547Q on NM_003573.2) | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV52588831; called by muse, mutect2, varscan2
- LTBP4 | c.3798G>C p.K1266N (on ENST00000308370 / NM_001042544.1; = p.K1229N on NM_003573.2) | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs769929356, COSV52579947, COSV99183600; called by muse, mutect2, varscan2
- MAGEB2 | c.933G>C p.L311F | Missense Mutation (SNP) | VAF 76/79 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV100975597, COSV66782277; called by muse, mutect2, varscan2
- MATN4 | c.1750G>A p.E584K (on ENST00000372754; = p.E543K on NM_003833.4) | Missense Mutation (SNP) | VAF 44/81 reads (54%) | PolyPhen possibly damaging (0.641); catalogued as COSV61353442; called by muse, mutect2, varscan2
- MCTP2 | c.2543C>G p.S848C | Missense Mutation (SNP) | VAF 97/183 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774344532; called by muse, mutect2, varscan2
- MDFIC | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1362372654, COSV57566700; called by muse, mutect2
- MIB2 | c.2879C>T p.S960L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.356); catalogued as rs1557625952; called by muse, mutect2, varscan2
- MTX1 | c.130C>G p.P44A | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs1382015687; called by muse, mutect2
- MUC5AC | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.22); catalogued as rs371703006; called by muse, mutect2, varscan2
- MYLK | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs989370486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO3A | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs914281712; called by muse, mutect2, varscan2
- MYO7B | c.4645G>A p.D1549N | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as rs200489409; called by muse, mutect2, varscan2
- NDFIP2 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV54526438; called by muse, mutect2, varscan2
- NDUFS1 | c.1810C>T p.Q604* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV99261041; called by muse, mutect2, varscan2
- NOP53 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54409254, COSV99622239; called by muse, mutect2, varscan2
- NOTCH4 | c.5929G>A p.E1977K | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as rs1239036035, COSV66679314, COSV66679913; called by muse, mutect2, varscan2
- NSUN6 | c.27G>C p.L9F | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV66034522; called by muse, mutect2, varscan2
- NUDT10 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs1557312292, COSV62854300; called by muse, mutect2, varscan2
- OR2H1 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745729217; called by muse, mutect2
- OR4K1 | c.666G>C p.L222F | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV53460479, COSV53461025; called by muse, mutect2
- PBXIP1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs143302711; called by muse, mutect2, varscan2
- PCF11 | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV53533706; called by muse, varscan2
- PCLO | c.12881G>A p.R4294K | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61632311; called by muse, mutect2, varscan2
- PKHD1L1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as COSV65756616; called by muse, mutect2, varscan2
- PLXDC1 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV59551817; called by muse, mutect2, varscan2
- PMS2 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs375507981, COSV56150639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNLDC1 | c.1225-1G>A p.X409_splice | Splice Site (SNP) | VAF 75/156 reads (48%) | catalogued as COSV51705526; called by muse, mutect2, varscan2
- PNPO | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs765350767; called by muse, mutect2, varscan2
- POLDIP2 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as rs1310596700; called by muse, mutect2, varscan2
- POLQ | c.5962G>A p.D1988N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51746952; called by muse, mutect2, varscan2
- PPL | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs1355493398; called by muse, mutect2, varscan2
- PPP1R27 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs770458996, COSV100367371; called by muse, mutect2, varscan2
- PRDM5 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV53357234; called by muse, mutect2, varscan2
- PRRC2C | c.5927C>T p.S1976L (on ENST00000367742; = p.S1974L on NM_015172.4) | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as rs770078502; called by muse, mutect2, varscan2
- PRRC2C | c.7950G>A p.M2650I (on ENST00000367742; = p.M2648I on NM_015172.4) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs765472222; called by muse, mutect2, varscan2
- PTPN13 | c.3619C>G p.Q1207E (on ENST00000411767 / NM_080683.3; = p.Q1188E on NM_006264.3) | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as rs748812599; called by muse, mutect2, varscan2
- RAD51C | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAD51D | c.345+7G>A | Splice Region (SNP) | VAF 19/48 reads (40%) | catalogued as rs1187944465; called by muse, mutect2, varscan2
- RALGAPA1 | c.3307G>A p.D1103N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV51885662; called by muse, mutect2, varscan2
- RAPGEF3 | c.1882G>A p.E628K (on ENST00000389212; = p.E586K on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); catalogued as COSV99406147; called by muse, mutect2, varscan2
- RELN | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.954); catalogued as COSV100633339; called by muse, mutect2, varscan2
- RERE | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61944851; called by muse, mutect2, varscan2
- RFX4 | c.1409C>T p.S470F (on ENST00000392842 / NM_213594.3; = p.S376F on NM_032491.6) | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV57571835; called by muse, mutect2, varscan2
- RIIAD1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV51884950, COSV51885528; called by muse, mutect2, varscan2
- RIT2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1262882444; called by muse, mutect2, varscan2
- RNF182 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV101337892; called by muse, mutect2
- RNF212 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 168/371 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs769642054; called by muse, mutect2, varscan2
- SATB1 | c.2082G>C p.Q694H | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100113084, COSV58669124; called by muse, mutect2, varscan2
- SDK2 | c.5861G>A p.R1954Q | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.383); catalogued as rs373850295; called by muse, mutect2, varscan2
- SEC24A | c.2153C>G p.S718C | Missense Mutation (SNP) | VAF 103/191 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs779769399, COSV59747940; called by muse, mutect2, varscan2
- SETD2 | c.4846G>T p.D1616Y | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57431441, COSV57444387; called by muse, mutect2, varscan2
- SEZ6L | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99961305; called by muse, mutect2, varscan2
- SGPP1 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs757862865; called by muse, mutect2
- SKIDA1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV71611015; called by muse, mutect2
- SLC12A2 | c.1779G>A p.M593I | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.577); catalogued as COSV52474950; called by muse, mutect2, varscan2
- SLC25A40 | c.852G>A p.W284* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV56693292; called by muse, mutect2, varscan2
- SLC26A1 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs754987516, COSV56102314; called by muse, mutect2, varscan2
- SLC26A8 | c.2761C>T p.H921Y | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV100839384; called by muse, mutect2, varscan2
- SLC30A1 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65360981; called by muse, mutect2, varscan2
- SLC35D1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 70/131 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as rs768672704; called by muse, mutect2, varscan2
- SMCHD1 | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55269463; called by muse, varscan2
- SMOC2 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771923108; called by muse, mutect2, varscan2
- SMYD4 | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.026); catalogued as COSV59712282; called by muse, mutect2, varscan2
- SPATA5 | c.2216C>G p.S739C | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56780482; called by muse, mutect2, varscan2
- SPCS1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs752641068, COSV51776974; called by muse, mutect2, varscan2
- SPRED2 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as rs1353857821; called by muse, mutect2, varscan2
- SPRED3 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV58312867; called by muse, mutect2, varscan2
- SRP68 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.343); catalogued as rs768400729; called by muse, mutect2
- SRSF1 | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99365191; called by muse, mutect2, varscan2
- STIL | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54547003, COSV99680619; called by muse, mutect2
- STOML1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51445010; called by muse, mutect2
- STOML1 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1295604541; called by muse, mutect2, varscan2
- SYNPO | c.2575C>T p.R859W (on ENST00000394243 / NM_001166208.2; = p.R615W on NM_007286.6) | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs781217685; called by muse, mutect2, varscan2
- TAAR1 | c.23T>A p.I8K | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51587852; called by muse, mutect2, varscan2
- TAF11 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.896); catalogued as COSV100781095; called by muse, mutect2, varscan2
- TBC1D4 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | catalogued as rs1425521776; called by muse, mutect2
- TBX5 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as CM004661, COSV100090760; called by muse, mutect2, varscan2
- TCHHL1 | c.1489G>C p.E497Q | Missense Mutation (SNP) | VAF 206/297 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV64285218; called by muse, mutect2, varscan2
- TENT5C | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65616283; called by muse, mutect2, varscan2
- TMEM132E | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58696395; called by muse, mutect2, varscan2
- TNS2 | c.2080G>A p.E694K (on ENST00000314250 / NM_170754.4; = p.E704K on NM_015319.2) | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs761637197; called by muse, mutect2, varscan2
- TRIM55 | c.1430C>G p.S477W | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.461); catalogued as rs767432272, COSV52544257; called by muse, mutect2, varscan2
- TRMT1 | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183720458, COSV52834165; called by muse, mutect2, varscan2
- TYW5 | c.888C>G p.F296L | Missense Mutation (SNP) | VAF 155/329 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774231572; called by muse, mutect2, varscan2
- UBE3A | c.2408G>A p.R803K | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.626); catalogued as rs1216352933; called by muse, mutect2
- UNC13B | c.2938G>C p.E980Q | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV65939209; called by muse, mutect2, varscan2
- UNC5D | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as rs759618055, COSV99774794; called by muse, mutect2, varscan2
- UPP2 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV99134831; called by muse, mutect2
- USO1 | c.2172G>A p.M724I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs779462764; called by muse, mutect2, varscan2
- VCAN | c.6618C>G p.F2206L | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV54099937; called by muse, mutect2, varscan2
- VEZT | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs200796011; called by muse, mutect2, varscan2
- VRK3 | c.147G>C p.K49N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV100371271; called by muse, mutect2, varscan2
- VWA5B1 | c.2870G>T p.G957V (on ENST00000375079; = p.G958V on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV57052661; called by muse, mutect2
- WNT10A | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs759060788; called by muse, mutect2, varscan2
- YY1AP1 | c.1736G>A p.R579K (on ENST00000295566 / NM_139118.2; = p.R522K on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.455); catalogued as rs1366631618, COSV55125406, COSV99804348; called by muse, mutect2, varscan2
- ZEB2 | c.2932G>A p.D978N | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as CM161499, COSV57964585; called by muse, mutect2, varscan2
- ZFP36L1 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60546129; called by muse, mutect2, varscan2
- ZFP36L2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV56697703; called by muse, mutect2, varscan2
- ZFY | c.1922C>A p.S641* | Nonsense Mutation (SNP) | VAF 75/76 reads (99%) | catalogued as COSV99324192; called by muse, mutect2, varscan2
- ZNF286A | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.357); catalogued as rs1448672204; called by muse, mutect2, varscan2
- ZNF347 | c.2326C>T p.Q776* | Nonsense Mutation (SNP) | VAF 71/127 reads (56%) | catalogued as rs753043886, COSV61968353; called by muse, mutect2, varscan2
- ZNF394 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 137/288 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.41); catalogued as rs765336766; called by muse, mutect2, varscan2
- ZNF804B | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60819892; called by muse, mutect2, varscan2
- ZNF804B | c.3954C>G p.F1318L | Missense Mutation (SNP) | VAF 154/307 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs746202470, COSV100306194, COSV60861766; called by muse, mutect2, varscan2
- AAK1 | c.2047C>T p.Q683* | Nonsense Mutation (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- ABCA4 | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.54); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABI3 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABR | c.2243C>T p.S748L (on ENST00000302538 / NM_021962.5; = p.S711L on NM_001092.5) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2
- ACTN4 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2
- ADAMTS16 | c.3191C>T p.S1064F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ADD3 | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2
- ADGRD1 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADNP2 | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AFAP1L2 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- AHNAK | c.8413G>A p.E2805K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AKAP13 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALDH9A1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 121/173 reads (70%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALG2 | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD27 | c.3010G>C p.E1004Q | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANO2 | c.1931+1G>A p.X644_splice (on ENST00000356134 / NM_001278597.3; = p.X648_splice on NM_001278596.3) | Splice Site (SNP) | VAF 57/124 reads (46%) | called by muse, mutect2, varscan2
- ANXA1 | c.850C>G p.Q284E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP21 | c.4300G>A p.E1434K | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP24 | c.1183C>G p.L395V (on ENST00000395184 / NM_001025616.3; = p.L302V on NM_031305.3) | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT tolerated (0.47); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ARHGAP5 | c.2695G>C p.E899Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ARHGEF37 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ARID1B | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- ATAD2 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ATMIN | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ATP10A | c.1364-3C>T | Splice Region (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- BCAR3 | c.2336A>C p.K779T | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.166); called by muse, varscan2
- BLNK | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BNC1 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BOK | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- BTBD7 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C2CD4D | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C3orf49 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CACNA1C | c.4727G>A p.G1576E | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, varscan2
- CAGE1 | c.196-1G>A p.X66_splice | Splice Site (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- CAPS2 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- CCDC168 | c.10986G>C p.K3662N | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCDC82 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2
- CD163 | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD300A | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CDH15 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CDH2 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 80/155 reads (52%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CDHR2 | c.1279G>C p.A427P | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CDK11A | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDYL | c.980G>A p.R327Q (on ENST00000328908 / NM_001368125.1; = p.R273Q on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CEL | c.1675G>A p.E559K (on ENST00000673714; = p.E556K on NM_001807.6) | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CENPF | c.6730G>A p.E2244K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CENPI | c.1880A>G p.K627R | Missense Mutation (SNP) | VAF 55/57 reads (96%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHRD | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CHRM5 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 124/263 reads (47%) | called by muse, mutect2, varscan2
- CLGN | c.1213C>G p.L405V | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CNOT11 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 75/132 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- CNTN1 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- COA6 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COG1 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL16A1 | c.891C>G p.I297M | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- COL4A4 | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 103/194 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CSF3R | c.1803G>C p.M601I | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- CTRC | c.492G>C p.W164C | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- DBF4 | c.1757G>C p.R586T | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DCAF6 | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF8 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DCTPP1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 81/165 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DDX1 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX16 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DIDO1 | c.4999G>A p.A1667T | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DLGAP5 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMXL2 | c.8159C>T p.S2720F | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- DNAH10 | c.11441-6G>C | Splice Region (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- DNAH14 | c.8095G>T p.E2699* (on ENST00000445597; = p.E3502* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 14/326 reads (4%) | called by muse, mutect2
- DNAH17 | c.2305C>G p.Q769E | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- DNAI1 | c.2043G>C p.E681D | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, varscan2
- DNAJC3 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOP1B | c.1882C>G p.L628V | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DRC7 | c.1269C>G p.I423M | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- DYNC1LI2 | c.598_599del p.P200Sfs*7 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by pindel, varscan2
- DZANK1 | c.1439G>T p.W480L (on ENST00000262547 / NM_001099407.1; = p.W287L on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFCAB5 | c.2653G>A p.G885S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- EHD1 | c.951G>C p.E317D | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ELP2 | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- EML6 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENPEP | c.1443+1G>A p.X481_splice | Splice Site (SNP) | VAF 55/231 reads (24%) | called by muse, mutect2, varscan2
- EP300 | c.3728+1G>A p.X1243_splice | Splice Site (SNP) | VAF 57/114 reads (50%) | called by muse, mutect2, varscan2
- ERP44 | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ETV3 | c.636G>T p.R212S | Missense Mutation (SNP) | VAF 40/382 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- EXOC3L4 | c.1829_1837del p.A610_S612del | In Frame Del (DEL) | VAF 32/73 reads (44%) | called by mutect2, pindel, varscan2
- EXPH5 | c.2405G>C p.R802T | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- FAM155A | c.116_124del p.R39_S41del | In Frame Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- FAM200A | c.1592C>G p.S531* | Nonsense Mutation (SNP) | VAF 40/71 reads (56%) | called by muse, mutect2, varscan2
- FAN1 | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAT1 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- FAT2 | c.7438G>C p.E2480Q | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- FAT3 | c.13480G>A p.E4494K | Missense Mutation (SNP) | VAF 102/197 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- FBXO44 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- FER1L5 | c.4779G>C p.K1593N (on ENST00000623019; = p.K1566N on NM_001293083.2) | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- FMO4 | c.123G>T p.W41C | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNBP4 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABRB1 | c.897G>C p.K299N | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAD1 | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); called by muse, mutect2
- GALNT13 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- GATB | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDPD4 | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- GFM2 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GJB6 | c.719A>C p.K240T | Missense Mutation (SNP) | VAF 72/78 reads (92%) | SIFT tolerated (0.14); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- GJC2 | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- GOLM2 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GPA33 | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR52 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF2E1 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- HBEGF | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HERC2 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.023); called by muse, mutect2
- HEXB | c.1280G>T p.S427I | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- HFM1 | c.597C>G p.N199K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HIVEP2 | c.2314C>G p.L772V | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.027); called by muse, mutect2
- HMGXB3 | c.589C>G p.R197G | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- HMGXB4 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- HSP90AA1 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HTT | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- HTT | c.6646C>T p.Q2216* | Nonsense Mutation (SNP) | VAF 42/142 reads (30%) | called by muse, mutect2, varscan2
- HUWE1 | c.3299C>T p.S1100L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- IFI16 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 50/171 reads (29%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.189G>C p.Q63H | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.62); called by muse, mutect2
- IGLON5 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IGSF6 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IL4I1 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- INTS1 | c.5407C>G p.L1803V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- INTS1 | c.1924C>A p.L642M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); called by muse, mutect2
- INTS13 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- INVS | c.1620C>G p.I540M | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ITGB8 | c.1030C>G p.Q344E | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KBTBD11 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.037); called by muse, mutect2
- KCNB1 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.152); called by muse, mutect2
- KCND1 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 47/47 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- KCNK10 | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- KCTD5 | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- KDM5D | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1109 | c.3172C>T p.Q1058* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- KIF1A | c.968C>G p.S323* | Nonsense Mutation (SNP) | VAF 64/103 reads (62%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.593C>G p.S198C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL31 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- LIFR | c.2668G>C p.E890Q | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LMOD3 | c.1044G>C p.Q348H | Missense Mutation (SNP) | VAF 112/220 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC53 | c.3661G>A p.E1221K | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- MACF1 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- MAF1 | c.410C>G p.S137* | Nonsense Mutation (SNP) | VAF 60/128 reads (47%) | called by muse, mutect2, varscan2
- MAMDC2 | c.1651+3G>A | Splice Region (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- MAP3K14 | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAPK7 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 102/180 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MARCHF7 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); called by muse, mutect2
- MAST4 | c.4564G>A p.E1522K (on ENST00000403625 / NM_001164664.2; = p.E1333K on NM_015183.3) | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAX | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- MCM9 | c.2993C>T p.P998L | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.029); called by muse, mutect2
- MED17 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.71); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MEGF9 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- MERTK | c.2975C>T p.S992L | Missense Mutation (SNP) | VAF 96/215 reads (45%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MGAM2 | c.2287C>T p.H763Y | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MIS18BP1 | c.874T>C p.C292R | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- MOB3B | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 61/129 reads (47%) | called by muse, mutect2, varscan2
- MPHOSPH8 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MRPL38 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTR | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MTRR | c.52del p.C18Afs*10 | Frame Shift Del (DEL) | VAF 50/109 reads (46%) | called by mutect2, pindel, varscan2
- MTUS1 | c.1678G>C p.D560H | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- MUC17 | c.9887C>G p.S3296C | Missense Mutation (SNP) | VAF 154/318 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MYBPC2 | c.1446G>C p.K482N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2
- MYLK3 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYORG | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- MYRIP | c.258C>G p.F86L | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NCOA1 | c.1849G>C p.D617H | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NCOA7 | c.1444C>G p.L482V | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NEDD1 | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- NEUROD6 | c.56G>C p.R19T | Missense Mutation (SNP) | VAF 191/198 reads (96%) | SIFT tolerated (0.19); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- NHLRC2 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLN | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- NRAP | c.2927C>G p.T976S (on ENST00000359988 / NM_001322945.2; = p.T941S on NM_006175.4) | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- NT5E | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2
- OR6C70 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- OSBPL11 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OSBPL3 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOF | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PAXIP1 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- PCCA | c.2121G>C p.V707= | Splice Region (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.1893G>C p.Q631H | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNX2 | c.4327C>G p.Q1443E | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDS5B | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PEPD | c.804G>C p.Q268H | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PER2 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- PIK3C2A | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated, low confidence (0.87); PolyPhen possibly damaging (0.738); called by muse, varscan2
- PIK3C2A | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.056); called by muse, varscan2
- PLEKHD1 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLPP3 | c.665G>C p.G222A | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- POLR3A | c.3367C>T p.P1123S | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- PPFIA2 | c.1940A>G p.Q647R | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PPHLN1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 92/185 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PPME1 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.035); called by muse, mutect2
- PPP4R1 | c.1816G>A p.D606N (on ENST00000400556 / NM_001042388.3; = p.D589N on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PREX1 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKDC | c.10690C>G p.Q3564E | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2
- PRKG1 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRSS3 | c.197C>G p.S66C (on ENST00000361005 / NM_007343.4; = p.S174C on NM_002771.3) | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.074); called by muse, varscan2
- PRUNE2 | c.4879G>C p.D1627H | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- PSPC1 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 41/44 reads (93%) | called by muse, mutect2, varscan2
- PTPRN | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRO | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- QRFPR | c.37C>G p.R13G | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RAB3GAP1 | c.1231C>G p.L411V | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- RABGAP1L | c.401G>A p.R134Q (on ENST00000489615 / NM_001243765.2; = p.R17Q on NM_001243764.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- RAD51AP2 | c.2605G>A p.D869N | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RALGAPA2 | c.3671C>G p.S1224C | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RANGAP1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RASA2 | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT tolerated (0.7); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- RCCD1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.417); called by muse, mutect2
- RCOR1 | c.104C>G p.S35W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- REC114 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- RFC3 | c.1068C>G p.F356L | Missense Mutation (SNP) | VAF 43/46 reads (93%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RFX8 | c.337G>A p.E113K (on ENST00000646446; = p.E42K on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- RGMB | c.336C>G p.I112M (on ENST00000513185 / NM_001366508.1; = p.I153M on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RILP | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RLF | c.3732T>G p.C1244W | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.408); called by muse, mutect2
- RNF135 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RNF214 | c.1466T>G p.L489R | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.323); called by muse, mutect2
- RPS6KB2 | c.1045C>T p.L349= | Splice Region (SNP) | VAF 105/217 reads (48%) | called by muse, mutect2, varscan2
- SCYL2 | c.1675T>G p.L559V | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, varscan2
- SEC24D | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.1); called by muse, mutect2
- SECISBP2L | c.1744G>C p.E582Q (on ENST00000559471 / NM_001193489.2; = p.E537Q on NM_014701.4) | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- SEMA3C | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA3F | c.942G>C p.W314C | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SENP5 | c.693G>C p.M231I | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- SEPTIN4 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SESN1 | c.1473G>A p.M491I (on ENST00000356644 / NM_001199933.1; = p.M550I on NM_014454.3) | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- SIRT1 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SKI | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SKP2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- SLC22A18 | c.405C>T p.A135= | Splice Region (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2
- SLC25A20 | c.24C>G p.I8M | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.547); called by muse, mutect2
- SLC38A2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 49/111 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC38A7 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2
- SLC44A3 | c.1355G>A p.R452K (on ENST00000271227 / NM_001114106.3; = p.R404K on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC5A2 | c.1793-3C>G | Splice Region (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- SLC5A4 | c.88T>G p.S30A | Missense Mutation (SNP) | VAF 98/195 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO4A1 | c.2152C>T p.L718F | Missense Mutation (SNP) | VAF 149/310 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SMC1A | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 71/85 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMC1A | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SMCHD1 | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- SMG7 | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SNRK | c.1749G>C p.Q583H | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SP100 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- SPAG1 | c.2296G>T p.E766* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- SPAG9 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPAG9 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SPATC1 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- SQSTM1 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- SRR | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SSBP3 | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- STEAP2 | c.599A>C p.E200A | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- STRN3 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 77/149 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- STRN4 | c.1154-3C>G | Splice Region (SNP) | VAF 11/135 reads (8%) | called by muse, mutect2
- SUPT20HL2 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- SYNM | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TANC1 | c.4168C>G p.L1390V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TAOK3 | c.2577G>C p.E859D | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TAPT1 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TBC1D14 | c.1615C>G p.Q539E | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- TELO2 | c.845C>G p.S282W | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- THNSL2 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TNFAIP2 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- TNNI3 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- TP73 | c.951G>C p.E317D | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRAF2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TRBJ2-5 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 50/94 reads (53%) | called by muse, mutect2, varscan2
- TRIO | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TRPS1 | c.2946G>C p.R982S (on ENST00000220888 / NM_001330599.2; = p.R995S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- TTC23L | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.12581C>T p.S4194L (on ENST00000591111; = p.S4148L on NM_003319.4) | Missense Mutation (SNP) | VAF 21/216 reads (10%) | called by muse, mutect2
- TULP1 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- UBD | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- UBE2F | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UCKL1 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ULK2 | c.1291C>G p.P431A | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP43 | c.2880G>C p.Q960H | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP9Y | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 42/43 reads (98%) | SIFT tolerated (0.12); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- UTP14C | c.1525C>G p.L509V | Missense Mutation (SNP) | VAF 69/72 reads (96%) | SIFT tolerated (0.17); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- VSTM2A | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- WDR1 | c.598G>A p.D200N (on ENST00000382452; = p.D60N on NM_005112.5) | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- WLS | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 138/300 reads (46%) | called by muse, mutect2
- WNK4 | c.2933C>T p.S978L | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB40 | c.899G>C p.R300T | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZC3H12C | c.2095C>T p.H699Y | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.055); called by muse, mutect2
- ZCCHC8 | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.6694G>C p.E2232Q | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ZMYND11 | c.453G>C p.K151N | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF200 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF462 | c.1235C>G p.S412C | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ZNF548 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF668 | c.473A>G p.H158R | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF684 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZSCAN16 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- A1BG | c.1215C>G p.L405= | Silent (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- AARS2 | c.1267C>T p.L423= | Silent (SNP) | VAF 58/60 reads (97%) | called by muse, mutect2, varscan2
- ABCA2 | c.5250G>T p.R1750= (on ENST00000614293; = p.R1720= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/134 reads (45%) | called by muse, mutect2, varscan2
- ACSM3 | c.666G>A p.V222= | Silent (SNP) | VAF 57/131 reads (44%) | called by muse, mutect2, varscan2
- ADAM32 | c.1110C>T p.F370= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as rs868282152, COSV101165421; called by muse, mutect2
- ADAMTS17 | c.507C>A p.S169= | Silent (SNP) | VAF 64/137 reads (47%) | called by muse, mutect2, varscan2
- ADCY6 | c.3219C>T p.I1073= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- ADGRF3 | c.2055C>T p.V685= (on ENST00000311519 / NM_001145168.1; = p.V486= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/121 reads (51%) | catalogued as rs1283213511; called by muse, mutect2, varscan2
- ALMS1 | c.5619G>A p.L1873= | Silent (SNP) | VAF 21/147 reads (14%) | called by muse, mutect2, varscan2
- ANK2 | c.6474G>A p.E2158= | Silent (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.1293G>A p.K431= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- ASIC4 | c.1311C>G p.L437= (on ENST00000347842 / NM_182847.3; = p.L456= on NM_018674.6) | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as rs1288400010; called by muse, mutect2
- ATXN1L | c.222G>C p.L74= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as rs1488291417; called by muse, mutect2
- BCAR1 | c.1812C>T p.L604= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV50791177; called by muse, mutect2, varscan2
- BDP1 | c.1296G>A p.Q432= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as rs80297681; called by muse, mutect2, varscan2
- BIRC6 | c.8184C>G p.L2728= | Silent (SNP) | VAF 56/122 reads (46%) | catalogued as rs768827206; called by muse, mutect2, varscan2
- BPNT2 | c.513C>T p.V171= | Silent (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- BRCA2 | c.4473G>T p.L1491= | Silent (SNP) | VAF 58/59 reads (98%) | called by muse, mutect2, varscan2
- C17orf98 | c.414C>T p.L138= | Silent (SNP) | VAF 152/287 reads (53%) | called by muse, mutect2, varscan2
- C6 | c.897C>T p.F299= | Silent (SNP) | VAF 73/176 reads (41%) | called by muse, mutect2, varscan2
- C9 | c.57C>T p.L19= | Silent (SNP) | VAF 47/112 reads (42%) | catalogued as rs1330093606; called by muse, mutect2
- CACNA1B | c.1404G>A p.E468= | Silent (SNP) | VAF 29/192 reads (15%) | catalogued as rs1564214269; called by muse, mutect2, varscan2
- CACNA1C | c.4770G>A p.K1590= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, varscan2
- CACNA1S | c.5574C>G p.L1858= | Silent (SNP) | VAF 26/202 reads (13%) | catalogued as COSV62943562; called by muse, mutect2, varscan2
- CARNS1 | c.219G>A p.L73= | Silent (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- CCIN | c.657C>T p.F219= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100631842, COSV58724663; called by muse, mutect2, varscan2
- CDC25B | c.711C>G p.L237= (on ENST00000245960 / NM_021873.3; = p.L223= on NM_004358.4) | Silent (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- CDC25C | c.807C>T p.I269= | Silent (SNP) | VAF 49/109 reads (45%) | called by muse, mutect2, varscan2
- CDHR2 | c.3297C>T p.L1099= | Silent (SNP) | VAF 91/214 reads (43%) | catalogued as rs371974737; called by muse, mutect2, varscan2
- CEACAM5 | c.510G>A p.E170= | Silent (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- CEL | c.741G>C p.L247= (on ENST00000673714; = p.L244= on NM_001807.6) | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs765704794, COSV60826228; called by muse, mutect2, varscan2
- CEP72 | c.1359C>A p.I453= | Silent (SNP) | VAF 44/95 reads (46%) | called by muse, mutect2, varscan2
- CETN1 | c.141C>T p.T47= | Silent (SNP) | VAF 120/254 reads (47%) | called by muse, mutect2, varscan2
- CHRM3 | c.345G>A p.L115= | Silent (SNP) | VAF 45/240 reads (19%) | catalogued as rs867335017; called by muse, mutect2, varscan2
- CLASP1 | c.729T>C p.D243= | Silent (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- CLSPN | c.3132G>A p.L1044= | Silent (SNP) | VAF 102/183 reads (56%) | called by muse, mutect2, varscan2
- CRCT1 | c.63C>A p.P21= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as rs1367674152; called by muse, mutect2, varscan2
- CRTC2 | c.2013G>C p.L671= | Silent (SNP) | VAF 115/162 reads (71%) | called by muse, mutect2, varscan2
- CUBN | c.8934C>T p.V2978= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- CYP11B1 | c.867C>T p.I289= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs1186627183; called by muse, mutect2, varscan2
- CYP2W1 | c.1437G>A p.P479= | Silent (SNP) | VAF 18/19 reads (95%) | catalogued as rs772121955, COSV58269635; called by muse, mutect2, varscan2
- CYTL1 | c.19C>T p.L7= | Silent (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2
- DDN | c.1971G>A p.R657= | Silent (SNP) | VAF 69/133 reads (52%) | catalogued as rs144149918; called by muse, mutect2, varscan2
- DHRS7C | c.783G>A p.E261= (on ENST00000330255 / NM_001220493.2; = p.E260= on NM_001105571.3) | Silent (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- DHX16 | c.1497G>C p.G499= | Silent (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- DLD | c.1449C>T p.V483= | Silent (SNP) | VAF 59/127 reads (46%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1404G>A p.L468= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV70098684; called by muse, mutect2
- DLX4 | c.63C>T p.L21= | Silent (SNP) | VAF 90/182 reads (49%) | called by muse, mutect2, varscan2
- DNAH10 | c.3822T>C p.L1274= (on ENST00000409039; = p.L1213= on NM_207437.3) | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as rs764381054; called by muse, mutect2, varscan2
- DNAH11 | c.2583C>T p.F861= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- DNAH17 | c.3492C>T p.I1164= | Silent (SNP) | VAF 68/144 reads (47%) | catalogued as rs1422718601, COSV67757630; called by muse, mutect2
- DNAH9 | c.8712G>A p.E2904= | Silent (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- DNAJC1 | c.192C>T p.L64= | Silent (SNP) | VAF 42/76 reads (55%) | called by muse, varscan2
- DOCK1 | c.2499G>A p.L833= | Silent (SNP) | VAF 87/197 reads (44%) | catalogued as COSV54756071; called by muse, mutect2, varscan2
- DTX1 | c.99G>A p.E33= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs778919730, COSV57496057; called by muse, mutect2, varscan2
- DUSP1 | c.153C>T p.I51= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV53321443; called by muse, mutect2, varscan2
- DUSP2 | c.429C>T p.C143= | Silent (SNP) | VAF 46/88 reads (52%) | catalogued as rs1225706124; called by muse, mutect2, varscan2
- EID2 | c.48G>A p.A16= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV66811049; called by muse, mutect2, varscan2
- EIF2B2 | c.171G>A p.L57= | Silent (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- EML5 | c.2974C>T p.L992= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV61347303; called by muse, mutect2, varscan2
- EPB41L3 | c.2622G>A p.A874= | Silent (SNP) | VAF 85/162 reads (52%) | catalogued as rs372107087; called by muse, mutect2, varscan2
- ESX1 | c.57C>T p.V19= | Silent (SNP) | VAF 189/192 reads (98%) | catalogued as rs782398321, COSV65424300; called by muse, mutect2, varscan2
- ESYT2 | c.429C>T p.L143= (on ENST00000613624; = p.L67= on NM_020728.3) | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as rs759744316; called by muse, mutect2, varscan2
- FABP2 | c.309G>A p.L103= | Silent (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- FAM135B | c.2517G>A p.Q839= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs770271569, COSV52710401; called by muse, mutect2, varscan2
- FAM32A | c.42G>A p.L14= | Silent (SNP) | VAF 74/144 reads (51%) | catalogued as rs1377422014; called by muse, mutect2, varscan2
- FCGR3A | c.633C>T p.F211= | Silent (SNP) | VAF 31/582 reads (5%) | called by muse, mutect2
- FLI1 | c.582C>T p.L194= | Silent (SNP) | VAF 34/53 reads (64%) | called by muse, mutect2, varscan2
- FUCA1 | c.303C>T p.F101= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as rs543713024; called by muse, mutect2, varscan2
- GABRR1 | c.813C>T p.L271= | Silent (SNP) | VAF 102/212 reads (48%) | catalogued as rs779636783; called by muse, mutect2, varscan2
- GAREM2 | c.972C>T p.F324= | Silent (SNP) | VAF 42/83 reads (51%) | catalogued as rs776557870, COSV68226242, COSV68226264; called by muse, mutect2, varscan2
- GATD3B | c.30G>C p.S10= | Silent (SNP) | VAF 65/129 reads (50%) | called by muse, mutect2, varscan2
- GFY | c.51G>C p.L17= | Silent (SNP) | VAF 54/95 reads (57%) | called by muse, mutect2, varscan2
- GLTPD2 | c.696G>A p.Q232= | Silent (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- GPALPP1 | c.15G>A p.L5= | Silent (SNP) | VAF 127/132 reads (96%) | catalogued as rs201710720; called by muse, mutect2, varscan2
- HAPLN2 | c.600C>G p.L200= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV54815292; called by muse, mutect2
- HCRTR1 | c.285G>A p.V95= | Silent (SNP) | VAF 46/80 reads (58%) | called by muse, mutect2, varscan2
- HDDC3 | c.42C>T p.F14= | Silent (SNP) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- HSPA8 | c.447C>T p.Y149= | Silent (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- IARS1 | c.3489C>T p.I1163= | Silent (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- IFI44L | c.1266G>A p.L422= | Silent (SNP) | VAF 63/133 reads (47%) | catalogued as COSV60726449; called by muse, mutect2, varscan2
- IKZF3 | c.1383C>T p.F461= | Silent (SNP) | VAF 85/167 reads (51%) | called by muse, mutect2, varscan2
- IQSEC1 | c.1845C>T p.I615= | Silent (SNP) | VAF 58/93 reads (62%) | called by muse, mutect2, varscan2
- ITPKB | c.210G>A p.R70= | Silent (SNP) | VAF 50/75 reads (67%) | called by muse, mutect2, varscan2
- ITPR3 | c.2103C>T p.N701= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as rs767808569; called by muse, mutect2, varscan2
- JAZF1 | c.603G>A p.Q201= | Silent (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- KCNJ12 | c.633C>T p.L211= | Silent (SNP) | VAF 56/122 reads (46%) | called by muse, mutect2, varscan2
- KDM2B | c.1371C>T p.L457= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs368940476; called by muse, mutect2
- KIAA1755 | c.1068C>T p.V356= | Silent (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2, varscan2
- KRT38 | c.411C>T p.L137= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as rs769171660, COSV55848072; called by muse, mutect2, varscan2
- KRTAP4-1 | c.204C>G p.V68= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as COSV66649864; called by muse, mutect2, varscan2
- LAMP3 | c.36C>T p.F12= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs1021385391; called by muse, mutect2, varscan2
- LHFPL5 | c.324C>T p.I108= | Silent (SNP) | VAF 80/168 reads (48%) | catalogued as COSV100799048; called by muse, mutect2, varscan2
- LRCH3 | c.2044C>T p.L682= | Silent (SNP) | VAF 83/180 reads (46%) | catalogued as COSV58396573; called by muse, mutect2, varscan2
- LRP1 | c.831C>T p.L277= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV54513747; called by muse, mutect2, varscan2
- LRRC59 | c.27G>A p.G9= | Silent (SNP) | VAF 77/163 reads (47%) | called by muse, mutect2, varscan2
- LTN1 | c.2701C>T p.L901= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as COSV63733712; called by muse, mutect2
- MACROD1 | c.591C>T p.D197= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs988459978; called by muse, mutect2, varscan2
- MANSC4 | c.336C>T p.T112= | Silent (SNP) | VAF 62/136 reads (46%) | catalogued as rs1449685232; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1314C>T p.L438= | Silent (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2, varscan2
- MATN1 | c.534C>T p.I178= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as rs778852998; called by muse, mutect2, varscan2
- MED17 | c.1485G>A p.L495= | Silent (SNP) | VAF 58/113 reads (51%) | called by muse, mutect2, varscan2
- MEGF8 | c.8355C>A p.L2785= (on ENST00000251268 / NM_001271938.2; = p.L2718= on NM_001410.3) | Silent (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
- MFSD6L | c.99C>T p.F33= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as rs1322190263; called by muse, mutect2, varscan2
- MINAR1 | c.9C>T p.T3= | Silent (SNP) | VAF 110/228 reads (48%) | called by muse, mutect2, varscan2
- MINDY2 | c.237C>T p.C79= | Silent (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- MPI | c.1035C>T p.F345= | Silent (SNP) | VAF 80/166 reads (48%) | called by muse, mutect2, varscan2
- MTA3 | c.1563G>A p.L521= (on ENST00000405094 / NM_001330442.2; = p.L464= on NM_001282755.1) | Silent (SNP) | VAF 73/153 reads (48%) | called by muse, mutect2, varscan2
- MTMR2 | c.69C>T p.D23= | Silent (SNP) | VAF 57/96 reads (59%) | catalogued as rs1200665801; called by muse, mutect2, varscan2
- MUC5AC | c.411C>T p.L137= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs1194186206; called by muse, mutect2, varscan2
- NF2 | c.42C>T p.L14= | Silent (SNP) | VAF 61/64 reads (95%) | called by muse, mutect2, varscan2
- NFAT5 | c.2706G>A p.Q902= | Silent (SNP) | VAF 88/199 reads (44%) | catalogued as COSV63025368; called by muse, mutect2, varscan2
- NLRC3 | c.1872C>T p.L624= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs755188612; called by muse, mutect2, varscan2
- NLRP4 | c.558C>T p.F186= | Silent (SNP) | VAF 117/225 reads (52%) | catalogued as COSV56716870; called by muse, mutect2, varscan2
- NLRP8 | c.810C>T p.L270= | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as rs117657068, COSV52594702; called by muse, mutect2, varscan2
- NMUR1 | c.18C>G p.L6= | Silent (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- NOTCH4 | c.4131C>A p.L1377= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as COSV66684486; called by muse, mutect2
- NPHS1 | c.1365C>T p.L455= | Silent (SNP) | VAF 60/118 reads (51%) | called by muse, mutect2, varscan2
- NRDC | c.2301C>T p.F767= | Silent (SNP) | VAF 96/196 reads (49%) | called by muse, mutect2, varscan2
- OLFML2A | c.291C>G p.L97= | Silent (SNP) | VAF 66/155 reads (43%) | called by muse, mutect2, varscan2
- OR13C5 | c.504C>T p.F168= | Silent (SNP) | VAF 101/238 reads (42%) | catalogued as COSV66164632; called by muse, mutect2, varscan2
- OR1L1 | c.894G>A p.V298= (on ENST00000373686; = p.V248= on NM_001005236.3) | Silent (SNP) | VAF 52/226 reads (23%) | called by muse, mutect2, varscan2
- OR4A5 | c.42C>T p.G14= | Silent (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- P2RX2 | c.39C>T p.T13= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs759308676; called by muse, mutect2, varscan2
- PABPC4L | c.651G>A p.L217= | Silent (SNP) | VAF 89/194 reads (46%) | called by muse, mutect2, varscan2
- PANK1 | c.15C>T p.V5= | Silent (SNP) | VAF 68/147 reads (46%) | catalogued as rs370694536; called by muse, mutect2, varscan2
- PCDHGB7 | c.786G>C p.L262= | Silent (SNP) | VAF 108/272 reads (40%) | called by muse, mutect2, varscan2
- PCNX2 | c.6126C>T p.L2042= | Silent (SNP) | VAF 44/58 reads (76%) | catalogued as rs377445053, COSV104383201; ClinVar: likely benign; called by muse, mutect2, varscan2
- PDGFRB | c.1689G>A p.E563= | Silent (SNP) | VAF 73/164 reads (45%) | called by muse, mutect2, varscan2
- PDK1 | c.255C>T p.V85= | Silent (SNP) | VAF 12/153 reads (8%) | catalogued as rs1356266723; called by muse, mutect2
- PEX11B | c.657C>T p.F219= | Silent (SNP) | VAF 60/233 reads (26%) | catalogued as COSV65199292; called by muse, mutect2, varscan2
- PIEZO2 | c.1944G>A p.A648= | Silent (SNP) | VAF 77/166 reads (46%) | catalogued as rs751249093; called by muse, mutect2, varscan2
- PLA2G15 | c.378C>T p.F126= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs760303124; called by muse, mutect2, varscan2
- PLK5 | c.207C>T p.F69= | Silent (SNP) | VAF 68/151 reads (45%) | catalogued as COSV58293989; called by muse, mutect2, varscan2
- PLPP4 | c.639C>T p.I213= | Silent (SNP) | VAF 49/99 reads (49%) | catalogued as rs769617780, COSV64827382; called by muse, mutect2, varscan2
- PLXNC1 | c.147C>A p.I49= | Silent (SNP) | VAF 53/125 reads (42%) | called by muse, mutect2, varscan2
- PNPLA3 | c.69C>T p.V23= | Silent (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- PPP1R1A | c.288G>A p.Q96= | Silent (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- PPP1R9B | c.363G>A p.V121= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs1456725751; called by muse, mutect2, varscan2
- PREX2 | c.3564C>T p.T1188= | Silent (SNP) | VAF 55/117 reads (47%) | called by muse, mutect2, varscan2
- PRMT1 | c.477C>A p.I159= | Silent (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- PSTK | c.150C>T p.I50= | Silent (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- PTBP3 | c.1587C>T p.L529= | Silent (SNP) | VAF 126/283 reads (45%) | called by muse, mutect2, varscan2
- PTPRD | c.3963G>A p.L1321= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV104419479; called by muse, mutect2, varscan2
- PWWP2B | c.96C>T p.F32= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- RAB11B | c.391C>T p.L131= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.1116C>T p.L372= | Silent (SNP) | VAF 59/116 reads (51%) | catalogued as rs1268842612; called by muse, mutect2, varscan2
- RARG | c.954C>T p.L318= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as COSV58432486; called by muse, mutect2, varscan2
- RHCE | c.579G>A p.K193= | Silent (SNP) | VAF 40/64 reads (63%) | catalogued as rs1441272625; called by muse, mutect2, varscan2
- RIMBP2 | c.1581C>T p.Y527= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs759112027, COSV55472554, COSV99898719; called by muse, mutect2, varscan2
- RIPK2 | c.1404G>A p.L468= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as COSV99609746; called by muse, mutect2, varscan2
- RIPOR2 | c.36T>C p.D12= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs903739065; called by muse, mutect2, varscan2
- RIT2 | c.210G>A p.L70= | Silent (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- RNF145 | c.1732C>T p.L578= (on ENST00000424310 / NM_001199383.2; = p.L606= on NM_144726.2) | Silent (SNP) | VAF 39/68 reads (57%) | called by muse, mutect2, varscan2
- RPUSD3 | c.765C>G p.L255= | Silent (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- SARAF | c.789C>T p.F263= | Silent (SNP) | VAF 11/270 reads (4%) | called by muse, mutect2
- SCN11A | c.3933C>T p.F1311= | Silent (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- SETD1A | c.1488G>A p.L496= | Silent (SNP) | VAF 50/89 reads (56%) | called by muse, mutect2, varscan2
- SIAH2 | c.657G>A p.V219= | Silent (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- SLC22A3 | c.324C>T p.L108= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs766552536; called by muse, mutect2, varscan2
- SLC22A8 | c.939C>T p.T313= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs372019665; called by muse, mutect2, varscan2
- SLC25A44 | c.906C>G p.L302= | Silent (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- SLC39A14 | c.114C>T p.I38= | Silent (SNP) | VAF 54/160 reads (34%) | called by muse, mutect2
- SLC5A2 | c.1170C>T p.L390= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- SLC7A13 | c.1353G>A p.K451= | Silent (SNP) | VAF 24/268 reads (9%) | catalogued as rs1401377621; called by muse, mutect2
- SPATS1 | c.507C>T p.V169= | Silent (SNP) | VAF 42/45 reads (93%) | called by muse, mutect2, varscan2
- SPEG | c.4350G>A p.R1450= | Silent (SNP) | VAF 102/209 reads (49%) | called by muse, mutect2, varscan2
- SPG11 | c.708G>A p.V236= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as rs1430128682; called by muse, mutect2, varscan2
- SPG11 | c.462G>A p.L154= | Silent (SNP) | VAF 22/37 reads (59%) | called by muse, mutect2, varscan2
- STK11 | c.135C>T p.L45= | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as rs1362065365; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYT4 | c.462G>T p.L154= | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as COSV99673971; called by muse, mutect2, varscan2
- TAAR5 | c.510C>T p.L170= | Silent (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- TBCA | c.18G>A p.V6= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs1379143649; called by muse, mutect2, varscan2
- TBXAS1 | c.1177C>T p.L393= | Silent (SNP) | VAF 97/201 reads (48%) | called by muse, mutect2, varscan2
- TCF20 | c.1254C>G p.L418= | Silent (SNP) | VAF 54/129 reads (42%) | catalogued as rs1488199816; called by muse, mutect2, varscan2
- TLR9 | c.1869C>T p.F623= | Silent (SNP) | VAF 51/107 reads (48%) | called by muse, mutect2, varscan2
- TLR9 | c.1605C>G p.L535= | Silent (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- TM7SF2 | c.876C>T p.V292= | Silent (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2
- TM7SF3 | c.1161C>T p.I387= | Silent (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- TMC6 | c.879C>T p.L293= | Silent (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2
- TMEM167B | c.31C>T p.L11= | Silent (SNP) | VAF 62/143 reads (43%) | catalogued as rs745638140; called by muse, mutect2, varscan2
- TMEM245 | c.69C>T p.V23= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs949893858; called by muse, mutect2, varscan2
- TMEM42 | c.96G>C p.A32= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV56643527; called by muse, mutect2
- TMPO | c.1368G>T p.L456= | Silent (SNP) | VAF 37/164 reads (23%) | called by muse, mutect2, varscan2
- TNFAIP2 | c.1689C>T p.F563= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs1413567424, COSV100281095; called by muse, varscan2
- TNFRSF10A | c.774G>C p.L258= | Silent (SNP) | VAF 12/157 reads (8%) | called by muse, mutect2
- TRAV13-2 | c.246C>A p.V82= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as rs147044366; called by muse, mutect2, varscan2
- TRH | c.240C>G p.L80= | Silent (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- TRIM46 | c.594C>T p.F198= | Silent (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- TRPM3 | c.1830G>A p.L610= (on ENST00000357533 / NM_001366142.2; = p.L453= on NM_020952.6) | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV62587549; called by muse, mutect2, varscan2
- TRPM8 | c.90G>C p.R30= | Silent (SNP) | VAF 61/156 reads (39%) | catalogued as COSV100223754; called by muse, mutect2, varscan2
- TSKU | c.774C>T p.V258= | Silent (SNP) | VAF 13/152 reads (9%) | called by muse, mutect2
- TSN | c.573G>A p.L191= | Silent (SNP) | VAF 72/146 reads (49%) | catalogued as rs764846807; called by muse, mutect2, varscan2
- TTC21B | c.3051C>T p.S1017= | Silent (SNP) | VAF 63/135 reads (47%) | catalogued as COSV54630063; called by muse, mutect2, varscan2
- TXNIP | c.204G>A p.E68= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs1271699423; called by muse, mutect2, varscan2
- TYSND1 | c.159C>T p.F53= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs745391748; called by muse, mutect2, varscan2
- UBASH3A | c.723C>T p.F241= | Silent (SNP) | VAF 130/233 reads (56%) | called by muse, mutect2, varscan2
- UBE3C | c.2619G>A p.L873= | Silent (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- UNC13B | c.4542G>A p.V1514= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as rs1366271627; called by muse, mutect2, varscan2
- UNC79 | c.7162C>T p.L2388= (on ENST00000393151 / NM_001346218.2; = p.L2211= on NM_020818.5) | Silent (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- UPF1 | c.531G>A p.G177= | Silent (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- VAV2 | c.171C>G p.L57= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV64083960; called by muse, mutect2, varscan2
- VCL | c.2013C>T p.L671= | Silent (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- VPS37D | c.63C>T p.I21= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs781876870; called by muse, mutect2, varscan2
- VSTM2L | c.501G>A p.E167= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as rs772759481; called by muse, varscan2
- WDR91 | c.627G>A p.L209= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs986104885; called by muse, mutect2, varscan2
- XRCC3 | c.954C>G p.L318= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs1360454779; called by muse, mutect2, varscan2
- ZBTB40 | c.1837C>T p.L613= | Silent (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- ZC3H12A | c.258G>A p.V86= | Silent (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- ZNF138 | c.420A>G p.Q140= (on ENST00000307355 / NM_001367572.1; = p.Q114= on NM_006524.4) | Silent (SNP) | VAF 110/200 reads (55%) | catalogued as rs745931171; called by muse, mutect2, varscan2
- ZNF507 | c.1749C>T p.I583= | Silent (SNP) | VAF 107/199 reads (54%) | called by muse, mutect2, varscan2
- ZYG11B | c.1554G>A p.L518= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV53754526; called by muse, mutect2, varscan2
- ZZEF1 | c.6822C>A p.I2274= | Silent (SNP) | VAF 58/126 reads (46%) | called by muse, mutect2, varscan2
- ABCC4 | c.75-21574C>T | Intron (SNP) | VAF 28/61 reads (46%) | catalogued as rs1225554773; called by muse, mutect2, varscan2
- ABCC6P1 | n.186G>C | RNA (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- ABCE1 | c.*815G>A | 3'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- ABHD10 | c.*1335G>A | 3'UTR (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- AC024598.1 | c.1130-985G>T | Intron (SNP) | VAF 76/155 reads (49%) | catalogued as COSV60825082; called by muse, mutect2, varscan2
- AC025040.2 | n.1772G>A | RNA (SNP) | VAF 8/170 reads (5%) | catalogued as rs952551433; called by muse, mutect2
- AC044798.1 | n.97C>G | RNA (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- AC068533.4 | c.564-12897C>G | Intron (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- AC068643.2 | n.593+3731G>C | Intron (SNP) | VAF 203/428 reads (47%) | called by muse, mutect2, varscan2
- AC093155.3 | c.-48G>A | 5'UTR (SNP) | VAF 69/175 reads (39%) | called by muse, mutect2, varscan2
- AC099548.2 | chr7:143836727 G>A | 5'Flank (SNP) | VAF 3/13 reads (23%) | catalogued as rs1325956950; called by muse, mutect2
- AC106795.1 | n.497-81C>G | Intron (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- AC107959.5 | c.-182+2066G>A | Intron (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- AC107959.5 | c.-182+2186C>T | Intron (SNP) | VAF 48/93 reads (52%) | called by muse, mutect2, varscan2
- AC116366.2 | c.-637-16116G>A | Intron (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- ACAD8 | c.1195+711C>G | Intron (SNP) | VAF 50/84 reads (60%) | called by muse, mutect2, varscan2
- ACAP2 | c.-152C>A | 5'UTR (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27195891 C>G | 3'Flank (SNP) | VAF 36/56 reads (64%) | called by muse, mutect2, varscan2
- ACBD6 | c.*1594G>A | 3'UTR (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2
- ACIN1 | c.-115G>A | 5'UTR (SNP) | VAF 12/174 reads (7%) | catalogued as COSV99399428; called by muse, mutect2
- ACOT7 | c.860-1463C>T | Intron (SNP) | VAF 26/56 reads (46%) | catalogued as rs1302610242; called by muse, mutect2, varscan2
- ACTR6 | c.68+20G>C | Intron (SNP) | VAF 111/232 reads (48%) | called by muse, mutect2, varscan2
- ACVR2A | c.*2335C>T | 3'UTR (SNP) | VAF 49/120 reads (41%) | called by muse, mutect2, varscan2
- ADAM10 | c.*1354C>T | 3'UTR (SNP) | VAF 35/70 reads (50%) | called by muse, mutect2, varscan2
- ADAR | c.*774C>T | 3'UTR (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- ADCY4 | c.*26C>T | 3'UTR (SNP) | VAF 83/179 reads (46%) | catalogued as rs1452110641; called by muse, mutect2, varscan2
- ADH1B | c.*434G>C | 3'UTR (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- AHCYL2 | c.*2027C>T | 3'UTR (SNP) | VAF 20/46 reads (43%) | catalogued as rs751135879; called by muse, mutect2, varscan2
- AHI1 | c.*296G>A | 3'UTR (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- AIP | c.-83G>A | 5'UTR (SNP) | VAF 56/141 reads (40%) | catalogued as COSV99653589; called by muse, mutect2, varscan2
- AK6 | c.*1048G>A | 3'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
725 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 725 other) are not listed here.
